Somatic mutation profile of tumor specimen TCGA-HI-7171-01A (aliquot TCGA-HI-7171-01A-12D-2114-08) from TCGA case TCGA-HI-7171, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.9 years (20,776 days).
Specimen TCGA-HI-7171-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 069c737c-3ad3-4f06-8da5-dcd29c51847f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HI-7171-10A (Blood Derived Normal), aliquot TCGA-HI-7171-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c9253fe-5fe5-4741-8956-b9db32f8590d

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, Splice Site 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 46/99 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.604+1G>T p.X202_splice | Splice Site (SNP) | VAF 36/101 reads (36%) | catalogued as COSV50999638; called by muse, mutect2, varscan2
- ABCA13 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs755379798, COSV70041468; called by muse, mutect2, varscan2
- AHNAK | c.12199A>T p.K4067* | Nonsense Mutation (SNP) | VAF 36/353 reads (10%) | catalogued as COSV57226350; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2363T>G p.L788W | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57751350; called by muse, mutect2
- C2orf42 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52448777, COSV52452323; called by muse, mutect2
- CDH2 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs199882009, COSV52274643; called by muse, mutect2, varscan2
- DYNC1LI2 | c.530-1G>A p.X177_splice | Splice Site (SNP) | VAF 19/23 reads (83%) | catalogued as COSV50755923; called by muse, mutect2, varscan2
- EFNA5 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs771409651, COSV60956544; called by muse, mutect2, varscan2
- GJC2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64513218; called by muse, mutect2, varscan2
- HTR2C | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs193920954, COSV52214562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL7R | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV57412122; called by muse, mutect2, varscan2
- OR51G1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV58970407; called by muse, mutect2, varscan2
- OR6C76 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100094149, COSV60389791; called by muse, mutect2, varscan2
- PRDM14 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1268843071, COSV52571864; called by muse, mutect2, varscan2
- RAC2 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1489649391, COSV50774567; called by muse, mutect2, varscan2
- SAV1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV61205565; called by muse, mutect2, varscan2
- SESN3 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781016923, COSV53583899, COSV99565871; called by muse, mutect2, varscan2
- SHC2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs766676985, COSV52748770; called by muse, mutect2, varscan2
- TNS1 | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779217268, COSV50751704; called by muse, varscan2
- C17orf78 | c.566T>A p.I189N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RPF2 | c.394-10_415del p.X132_splice | Splice Site (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel
- HNF1A | c.1014C>T p.G338= | Silent (SNP) | VAF 35/176 reads (20%) | catalogued as rs763412043, COSV57459631; called by muse, mutect2, varscan2
- JPH4 | c.1581C>T p.D527= | Silent (SNP) | VAF 99/315 reads (31%) | catalogued as rs775876728, COSV58113031; called by muse, mutect2, varscan2
- MINAR1 | c.150C>G p.L50= | Silent (SNP) | VAF 64/142 reads (45%) | catalogued as COSV59585746; called by muse, mutect2, varscan2
- MYF5 | c.108G>T p.V36= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV57356270; called by muse, mutect2, varscan2
- NEUROD6 | c.306C>T p.R102= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs774543274, COSV51772948; called by muse, mutect2
- NSDHL | c.921A>G p.L307= | Silent (SNP) | VAF 40/46 reads (87%) | catalogued as rs375828345, COSV64744984; called by muse, mutect2, varscan2
- OR3A2 | c.597C>T p.S199= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as rs202057099, COSV68695244; called by muse, mutect2
- SIGIRR | c.435C>T p.N145= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as COSV58989481; called by muse, mutect2, varscan2
- TBCC | c.9C>T p.S3= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs537953279, COSV55130640; called by muse, mutect2, varscan2
